Somatic mutation profile of tumor specimen HCM-CSHL-0405-C25-01A (aliquot HCM-CSHL-0405-C25-01A-11D-A78L-36) from HCMI case HCM-CSHL-0405-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 48.3 years (17,648 days).
Specimen HCM-CSHL-0405-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0df4dd6-e78e-496e-9577-46b53008d72b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0405-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0405-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e914c4a2-dcdc-448b-a862-6c18363fc509

The open-access MAF lists 41 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 9, Intron 3, In Frame Del 2, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 53/208 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.96+2T>G p.X32_splice | Splice Site (SNP) | VAF 73/244 reads (30%) | hotspot (GDC flag); catalogued as COSV53738354; called by muse, mutect2, varscan2
- AXDND1 | c.155C>G p.T52S | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as COSV62648428; called by muse, mutect2
- CBFA2T3 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 53/312 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs755685805; called by muse, mutect2, varscan2
- CEP104 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs755536798, COSV65517864; called by muse, mutect2, varscan2
- CLMN | c.2679_2681del p.E893del | In Frame Del (DEL) | VAF 26/70 reads (37%) | catalogued as rs1415417324; called by pindel, varscan2
- DHX37 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 97/476 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs368046437, COSV100438873, COSV104394572; called by muse, mutect2, varscan2
- DNASE1L3 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs773990318; called by muse, mutect2, varscan2
- DSTYK | c.2141A>G p.H714R | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs1553361152; called by muse, mutect2, varscan2
- LRFN1 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 50/562 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs1568569338; called by muse, mutect2
- NOS2 | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375448100, COSV58227866; called by muse, mutect2, varscan2
- PDGFRA | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs779332376, COSV57271921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAG | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.641); catalogued as rs371502229, COSV68591185; called by muse, mutect2, varscan2
- SEMA5A | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 74/300 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs375422150; called by muse, mutect2, varscan2
- TEX13B | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 66/112 reads (59%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.872); catalogued as COSV57202560; called by muse, mutect2, varscan2
- TLCD4 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1250183068, COSV64632391; called by muse, mutect2, varscan2
- ANXA4 | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDKN2A | c.185_208del p.L62_E69del | In Frame Del (DEL) | VAF 163/659 reads (25%) | called by mutect2, varscan2
- FERMT2 | c.167_168del p.K56Rfs*4 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- IGHV3-13 | c.32T>A p.V11D | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ITGA7 | c.3112C>A p.L1038M (on ENST00000555728; = p.L994M on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/540 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by muse, mutect2
- NOMO2 | c.1716G>T p.E572D | Missense Mutation (SNP) | VAF 62/402 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RASAL2 | c.3145C>T p.Q1049* | Nonsense Mutation (SNP) | VAF 33/213 reads (15%) | called by muse, mutect2, varscan2
- ROBO4 | c.1571G>T p.W524L | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SOX11 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 17/402 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPTA1 | c.2749G>A p.E917K | Missense Mutation (SNP) | VAF 247/531 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- TDP1 | c.419A>G p.E140G | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ADAMTS16 | c.1770G>A p.S590= | Silent (SNP) | VAF 58/247 reads (23%) | catalogued as rs201912376, COSV56981644; called by muse, mutect2, varscan2
- GCN1 | c.1473C>T p.A491= | Silent (SNP) | VAF 77/279 reads (28%) | catalogued as rs200880565; called by muse, mutect2, varscan2
- IGDCC4 | c.474G>T p.G158= | Silent (SNP) | VAF 83/396 reads (21%) | called by muse, mutect2, varscan2
- IGHV3OR16-9 | c.180C>T p.Y60= | Silent (SNP) | VAF 97/330 reads (29%) | catalogued as rs752509559, COSV61211545; called by muse, mutect2, varscan2
- KRTAP19-4 | c.132C>T p.N44= | Silent (SNP) | VAF 99/392 reads (25%) | catalogued as rs766112768, COSV61858651; called by muse, mutect2, varscan2
- MRPS23 | c.66C>T p.A22= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs755842412, COSV100551451; called by muse, mutect2, varscan2
- SCN2A | c.4977G>A p.A1659= | Silent (SNP) | VAF 54/233 reads (23%) | catalogued as rs1250394077, COSV99333666; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDPCP | c.954C>A p.I318= | Silent (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- ZC3H4 | c.3882C>T p.F1294= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs541784925; called by muse, mutect2, varscan2
- C22orf34 | n.153C>T | RNA (SNP) | VAF 92/367 reads (25%) | catalogued as rs893078168; called by muse, mutect2, varscan2
- DENND5B | c.128-45083G>A | Intron (SNP) | VAF 11/79 reads (14%) | catalogued as rs1000397565; called by muse, mutect2, varscan2
- GRIK4 | c.907-2142G>A | Intron (SNP) | VAF 19/86 reads (22%) | catalogued as rs752888574; called by muse, mutect2, varscan2
- PTGIS | c.*10C>T | 3'UTR (SNP) | VAF 28/560 reads (5%) | called by muse, mutect2
- SDK1 | c.1151-846A>T | Intron (SNP) | VAF 13/66 reads (20%) | called by muse, varscan2
